Somatic mutation profile of tumor specimen 0DV994 from CCDI case PBCJXK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 3.0 years (1,090 days).
Specimen 0DV994: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5bbc839-c69c-42ce-b802-903815480458.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV98M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d06393a3-c381-450f-b302-77ee684e4d28

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 4, 3'UTR 2, Nonsense Mutation 1, Silent 1, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPNE5 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 175/425 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs1479482644; called by muse, mutect2, varscan2
- DMP1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 142/377 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs149078199; called by muse, mutect2, varscan2
- GP2 | c.961G>A p.A321T (on ENST00000381362 / NM_001007240.3; = p.A318T on NM_001502.4) | Missense Mutation (SNP) | VAF 83/585 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.401); catalogued as COSV56896021; called by muse, mutect2, varscan2
- NUP205 | c.4232G>A p.G1411D | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53657032; called by muse, mutect2
- PARK7 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 287/347 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs182164240, COSV58580728; called by muse, mutect2, varscan2
- PLXNB2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs763537846, COSV63780535; called by muse, mutect2
- BCOR | c.4257del p.F1419Lfs*65 (on ENST00000378444 / NM_001123385.2; = p.F1385Lfs*65 on NM_017745.6) | Frame Shift Del (DEL) | VAF 134/218 reads (61%) | called by mutect2, pindel, varscan2
- COG1 | c.2074-7T>C | Splice Region (SNP) | VAF 88/369 reads (24%) | called by muse, mutect2, varscan2
- NEU4 | c.203G>A p.W68* (on ENST00000391969 / NM_001167602.3; = p.W80* on NM_080741.4) | Nonsense Mutation (SNP) | VAF 13/247 reads (5%) | called by muse, mutect2
- OR6J1 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 22/657 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- TNIP1 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 31/1018 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YES1 | c.1346T>A p.F449Y | Missense Mutation (SNP) | VAF 147/654 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ZNF524 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 110/444 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- ZKSCAN8 | c.286C>T p.L96= | Silent (SNP) | VAF 141/359 reads (39%) | called by muse, mutect2, varscan2
- BCL10 | c.57+54G>A | Intron (SNP) | VAF 108/267 reads (40%) | called by muse, mutect2
- CWH43 | c.*25G>T | 3'UTR (SNP) | VAF 54/540 reads (10%) | called by muse, mutect2
- DISP2 | c.-63_-62insACC | 5'UTR (INS) | VAF 5/53 reads (9%) | catalogued as rs1018445073; called by mutect2, pindel
- FBXO3 | c.105-92G>C | Intron (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- MPC1 | c.72-96G>A | Intron (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- NAPG | c.*61G>A | 3'UTR (SNP) | VAF 76/242 reads (31%) | called by muse, mutect2, varscan2
- STK24 | c.1295+51G>T | Intron (SNP) | VAF 73/283 reads (26%) | called by muse, mutect2, varscan2
